Somatic mutation profile of tumor specimen HCM-CSHL-0323-C20-01A (aliquot HCM-CSHL-0323-C20-01A-11D-A78T-36) from HCMI case HCM-CSHL-0323-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.2 years (19,788 days).
Specimen HCM-CSHL-0323-C20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2723614-2e94-4a96-977d-07c5efea582e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0323-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0323-C20-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6679e191-5737-4084-98a6-21770e1cbacf

The open-access MAF lists 107 somatic variants for this specimen: 70 protein-altering or splice-affecting, 27 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 27, Nonsense Mutation 4, 5'UTR 4, Intron 3, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 36/299 reads (12%) | catalogued as rs782138777, CM088308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 115/224 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as rs371524413, CM984589, COSV52698013, COSV52700732, COSV52710835, COSV52891661; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AFF1 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100320468; called by muse, mutect2, varscan2
- AGBL1 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767364604, COSV101224391, COSV66858368; called by muse, mutect2, varscan2
- AL645922.1 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 127/527 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs751852076, COSV54960479; called by muse, mutect2, varscan2
- AMER1 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 186/295 reads (63%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs778813513; called by muse, mutect2, varscan2
- ARHGAP21 | c.5810C>T p.A1937V | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs771670801; called by muse, mutect2, varscan2
- ATG2B | c.4601C>G p.T1534R | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV104379645; called by muse, mutect2, varscan2
- CCDC80 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs769656953, COSV99244981; called by muse, mutect2, varscan2
- CCER1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62647334; called by muse, mutect2, varscan2
- CNTNAP2 | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); catalogued as COSV62242531; called by muse, mutect2, varscan2
- DCAF4L2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1279696544, COSV60476552; called by muse, mutect2, varscan2
- DMD | c.5795A>T p.Q1932L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.839); catalogued as COSV63790408; called by muse, mutect2, varscan2
- FAF2 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs1028677538; called by muse, mutect2, varscan2
- GALNTL6 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV72552951; called by muse, mutect2, varscan2
- HECW1 | c.4463C>T p.A1488V | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs192568048; called by muse, mutect2, varscan2
- HEY2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV64240160; called by muse, mutect2, varscan2
- HM13 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100159626; called by muse, mutect2, varscan2
- IGSF9B | c.2875C>T p.R959W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs775176299; called by muse, mutect2, varscan2
- NPIPB11 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 274/1372 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.913); catalogued as rs775513952; called by muse, varscan2
- NSMF | c.764C>T p.A255V (on ENST00000371475 / NM_001130969.3; = p.A253V on NM_015537.4) | Missense Mutation (SNP) | VAF 87/540 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1281484579, COSV52996791; called by muse, mutect2, varscan2
- PAPPA2 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs777147973, COSV62783931; called by muse, mutect2, varscan2
- PCDHA1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 128/584 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65372473; called by muse, mutect2, varscan2
- PMCH | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100268343; called by muse, mutect2, varscan2
- PPP1R9A | c.2513G>A p.R838K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV56883912; called by muse, mutect2, varscan2
- PTPRA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 44/175 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as rs1012156940, COSV53786521; called by muse, mutect2, varscan2
- RTL4 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100465994; called by muse, mutect2, varscan2
- SLC6A5 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs750833001, COSV54227304; called by muse, mutect2, varscan2
- SOD3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 126/515 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs1214005453; called by muse, mutect2, varscan2
- SSNA1 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.274); catalogued as rs1388709781; called by muse, mutect2, varscan2
- TAL1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750834196, COSV53747247; called by muse, mutect2, varscan2
- THOC7 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs745955974; called by muse, mutect2, varscan2
- WHRN | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs1388198744; called by muse, mutect2, varscan2
- ZFP36L2 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 588/888 reads (66%) | catalogued as COSV56698061; called by mutect2, varscan2
- ZNF215 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs780015579, COSV53491912; called by muse, mutect2, varscan2
- ZNF454 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as rs780417342, COSV60766966; called by muse, mutect2, varscan2
- ZNF462 | c.3619G>T p.G1207W | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473232; called by muse, mutect2, varscan2
- ZNF536 | c.669C>A p.D223E | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.654); catalogued as rs1473327018; called by muse, mutect2, varscan2
- AGRN | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, varscan2
- ANK2 | c.8874A>T p.E2958D | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- BAALC | c.397C>G p.L133V (on ENST00000297574 / NM_001364874.1; = p.L98V on NM_024812.3) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CACNA1C | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CASR | c.2661G>T p.Q887H (on ENST00000490131; = p.Q964H on NM_000388.4) | Missense Mutation (SNP) | VAF 212/569 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CEP44 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- CHFR | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL5A2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 75/503 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCAF12L2 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC19 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ERI1 | c.966G>T p.M322I | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM155A | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM161A | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 42/589 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- FLACC1 | c.694A>T p.M232L | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HMGA2 | c.80G>T p.R27I | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ITGAX | c.1715T>A p.I572N | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KRTAP13-1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRGUK | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- MGAT5 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 53/365 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- MOBP | c.266C>T p.A89V (on ENST00000420739; = p.A113V on NM_001278322.2) | Missense Mutation (SNP) | VAF 50/313 reads (16%) | PolyPhen benign (0.007); called by muse, varscan2
- MSI1 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PAX3 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 54/356 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- POLB | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2
- PRAMEF6 | c.354dup p.A119Sfs*44 | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- SLC4A2 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- TBC1D32 | c.208A>T p.M70L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TG | c.3696G>T p.E1232D | Missense Mutation (SNP) | VAF 75/363 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMC3 | c.1323C>G p.F441L | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, varscan2
- USP19 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 25/158 reads (16%) | called by muse, mutect2, varscan2
- XPO4 | c.2131G>C p.V711L | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF638 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZSWIM2 | c.1741G>C p.V581L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS16 | c.2094C>G p.V698= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs779376714, COSV56983966; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2658C>T p.F886= | Silent (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- AMPD2 | c.1905G>A p.G635= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- CAND2 | c.1311G>T p.V437= (on ENST00000456430 / NM_001162499.2; = p.V344= on NM_012298.3) | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- DCAF1 | c.3322C>T p.L1108= | Silent (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- DSP | c.7149C>T p.S2383= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- EPHB6 | c.171C>T p.D57= | Silent (SNP) | VAF 78/465 reads (17%) | catalogued as rs780410425; called by muse, mutect2, varscan2
- EPS15L1 | c.606C>T p.S202= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as rs767315898, COSV50169599; called by muse, mutect2, varscan2
- FKRP | c.786C>T p.R262= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs1430767903; called by muse, mutect2, varscan2
- HEG1 | c.2172G>A p.T724= | Silent (SNP) | VAF 78/464 reads (17%) | called by muse, mutect2, varscan2
- HEMGN | c.1224C>T p.L408= | Silent (SNP) | VAF 77/520 reads (15%) | called by muse, mutect2, varscan2
- HOXA1 | c.900G>A p.P300= | Silent (SNP) | VAF 183/393 reads (47%) | catalogued as rs752269739, COSV58030183; called by muse, mutect2, varscan2
- HSP90AA1 | c.180G>C p.R60= | Silent (SNP) | VAF 60/259 reads (23%) | called by muse, mutect2, varscan2
- JPH3 | c.969C>T p.Y323= | Silent (SNP) | VAF 68/248 reads (27%) | catalogued as rs376157795; called by muse, mutect2, varscan2
- LRRC7 | c.261G>A p.E87= (on ENST00000651989 / NM_001370785.2; = p.E54= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 45/246 reads (18%) | catalogued as rs770324406, COSV50547803; called by muse, mutect2, varscan2
- METTL6 | c.576G>A p.L192= | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- NCOR1 | c.5295G>A p.E1765= | Silent (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- NYX | c.468C>T p.A156= | Silent (SNP) | VAF 51/138 reads (37%) | called by muse, mutect2, varscan2
- OR8H2 | c.507C>T p.Y169= | Silent (SNP) | VAF 51/223 reads (23%) | catalogued as rs576066178, COSV57944167, COSV57947973; called by muse, mutect2, varscan2
- PLAT | c.732G>A p.L244= | Silent (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.1593C>T p.S531= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs767414198; called by muse, mutect2, varscan2
- PRPF40A | c.1770C>T p.A590= | Silent (SNP) | VAF 36/336 reads (11%) | called by muse, mutect2, varscan2
- RYR3 | c.2253C>A p.P751= | Silent (SNP) | VAF 61/211 reads (29%) | called by muse, mutect2, varscan2
- SWSAP1 | c.156C>T p.T52= (on ENST00000312423; = p.T73= on NM_175871.4) | Silent (SNP) | VAF 88/364 reads (24%) | called by muse, varscan2
- TRPS1 | c.1752G>A p.P584= (on ENST00000220888 / NM_001330599.2; = p.P597= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/323 reads (20%) | catalogued as rs1460762540, COSV99629754; called by muse, mutect2, varscan2
- ZNF133 | c.1425C>T p.F475= (on ENST00000316358 / NM_001352454.2; = p.F474= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- ZNF835 | c.936C>T p.G312= | Silent (SNP) | VAF 77/338 reads (23%) | catalogued as rs776603650, COSV73379206, COSV73379497; called by muse, mutect2, varscan2
- ABCA8 | c.3918+43A>G | Intron (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- ASL | c.*34G>A | 3'UTR (SNP) | VAF 224/479 reads (47%) | catalogued as rs548464700, COSV59189353; called by muse, mutect2, varscan2
- CXCL3 | c.308+37C>T | Intron (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- GMFB | c.-6A>G | 5'UTR (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- GPR180 | c.-5C>T | 5'UTR (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2, varscan2
- HSD17B12 | c.-16G>A | 5'UTR (SNP) | VAF 41/183 reads (22%) | catalogued as rs1467937755; called by muse, mutect2, varscan2
- LINC01164 | n.1029G>A | RNA (SNP) | VAF 38/128 reads (30%) | catalogued as rs192498630; called by muse, mutect2
- REXO1L1P | chr8:85655105 C>T | 3'Flank (SNP) | VAF 102/2058 reads (5%) | catalogued as rs757619904; called by muse, mutect2
- SYCP2 | c.-4C>A | 5'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- TAFA5 | c.112+54995C>T | Intron (SNP) | VAF 35/145 reads (24%) | catalogued as rs923041679; called by muse, mutect2
